Somatic mutation profile of tumor specimen TCGA-CZ-5989-01A (aliquot TCGA-CZ-5989-01A-11D-1669-08) from TCGA case TCGA-CZ-5989, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage II; Tumor grade: G2; Age at diagnosis: 60.7 years (22,170 days).
Specimen TCGA-CZ-5989-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8397b78d-0e87-4409-861a-2b05ad1a4397.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CZ-5989-11A (Solid Tissue Normal), aliquot TCGA-CZ-5989-11A-01D-1669-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a6670cb9-cac8-47bd-b1e9-9181cea8ae61

The open-access MAF lists 47 somatic variants for this specimen: 36 protein-altering or splice-affecting, 10 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 26, Silent 10, Frame Shift Del 3, Nonsense Mutation 3, Frame Shift Ins 1, 3'UTR 1, Splice Region 1, In Frame Ins 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCC9 | c.2280G>T p.W760C | Missense Mutation (SNP) | VAF 12/81 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53973942; called by muse, mutect2, varscan2
- ATG4C | c.1054T>G p.F352V | Missense Mutation (SNP) | VAF 24/99 reads (24%) | SIFT tolerated (0.45); PolyPhen benign (0.06); catalogued as COSV58606104; called by muse, mutect2, varscan2
- CCBE1 | c.1079G>A p.R360Q | Missense Mutation (SNP) | VAF 45/221 reads (20%) | SIFT tolerated (0.28); PolyPhen benign (0.001); catalogued as rs200219373, COSV67949911, COSV67950117; called by muse, mutect2, varscan2
- CDC14A | c.931T>A p.C311S | Missense Mutation (SNP) | VAF 9/274 reads (3%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV60558826; called by muse, mutect2
- CELF6 | c.381T>G p.S127R | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.047); catalogued as COSV54716914; called by muse, mutect2, varscan2
- CEP76 | c.1701G>C p.E567D | Missense Mutation (SNP) | VAF 5/84 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.521); catalogued as COSV50866941; called by muse, mutect2
- COL5A3 | c.4825T>A p.Y1609N | Missense Mutation (SNP) | VAF 3/21 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53411866; called by muse, mutect2
- EIF6 | c.124C>G p.L42V | Missense Mutation (SNP) | VAF 22/122 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.555); catalogued as COSV65583224; called by muse, mutect2, varscan2
- FBLN7 | c.1078G>A p.A360T | Missense Mutation (SNP) | VAF 27/127 reads (21%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.974); catalogued as COSV55616343; called by muse, mutect2, varscan2
- GBF1 | c.3286G>T p.G1096C (on ENST00000369983 / NM_001377137.1; = p.G1095C on NM_004193.3) | Missense Mutation (SNP) | VAF 18/71 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV64145410; called by muse, mutect2, varscan2
- MYLK3 | c.229G>A p.G77R | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT tolerated (0.54); PolyPhen benign (0.277); catalogued as rs143624767; called by muse, mutect2, varscan2
- NCAPG2 | c.442T>A p.C148S | Missense Mutation (SNP) | VAF 8/128 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV51987108, COSV51988273; called by muse, mutect2
- NCOA3 | c.256+2T>C p.X86_splice | Splice Site (SNP) | VAF 11/58 reads (19%) | catalogued as COSV59069258; called by muse, mutect2, varscan2
- NOD2 | c.2974A>T p.N992Y | Missense Mutation (SNP) | VAF 13/73 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV56051309; called by muse, mutect2, varscan2
- PBRM1 | c.3703del p.V1235Cfs*34 (on ENST00000296302 / NM_001366071.2; = p.V1210Cfs*34 on NM_018313.5) | Frame Shift Del (DEL) | VAF 16/78 reads (21%) | catalogued as COSV56280027; called by mutect2, pindel, varscan2
- PFDN6 | c.35A>G p.E12G | Missense Mutation (SNP) | VAF 15/76 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.468); catalogued as COSV65842342; called by muse, mutect2, varscan2
- PRSS16 | c.1261G>A p.A421T | Missense Mutation (SNP) | VAF 44/174 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.885); catalogued as rs1174795454, COSV57915671; called by muse, mutect2, varscan2
- RAPGEF2 | c.1859G>A p.R620H | Missense Mutation (SNP) | VAF 75/235 reads (32%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.86); catalogued as COSV52428795; called by muse, mutect2, varscan2
- RICTOR | c.3194A>G p.N1065S | Missense Mutation (SNP) | VAF 31/136 reads (23%) | SIFT tolerated (0.84); PolyPhen benign (0); catalogued as rs199854036, COSV57123092; called by muse, mutect2, varscan2
- SPRYD4 | c.366G>A p.W122* | Nonsense Mutation (SNP) | VAF 47/251 reads (19%) | catalogued as COSV57665560; called by muse, mutect2, varscan2
- SRP68 | c.1373C>A p.T458N | Missense Mutation (SNP) | VAF 14/124 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.439); catalogued as COSV57162888; called by muse, mutect2
- THNSL1 | c.77A>G p.D26G | Missense Mutation (SNP) | VAF 28/101 reads (28%) | SIFT tolerated, low confidence (0.6); PolyPhen benign (0); catalogued as rs767278526, COSV64479407; called by muse, mutect2, varscan2
- TRIM55 | c.1107A>C p.E369D | Missense Mutation (SNP) | VAF 18/78 reads (23%) | SIFT tolerated (0.13); PolyPhen benign (0.092); catalogued as COSV52546772; called by muse, mutect2, varscan2
- TRPV1 | c.1476G>A p.G492= | Splice Region (SNP) | VAF 4/20 reads (20%) | catalogued as COSV51519336; called by muse, mutect2, varscan2
- TSNARE1 | c.1481C>T p.S494L | Missense Mutation (SNP) | VAF 16/64 reads (25%) | SIFT tolerated (0.66); PolyPhen benign (0.001); catalogued as COSV56176928; called by muse, varscan2
- UNC45A | c.62T>A p.V21E | Missense Mutation (SNP) | VAF 22/108 reads (20%) | SIFT tolerated (0.7); PolyPhen benign (0.059); catalogued as COSV57746075; called by muse, mutect2, varscan2
- VAV2 | c.590A>T p.D197V (on ENST00000371850 / NM_001134398.2; = p.D192V on NM_003371.4) | Missense Mutation (SNP) | VAF 15/61 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.872); catalogued as COSV64082288; called by muse, mutect2, varscan2
- XYLT2 | c.813C>A p.D271E | Missense Mutation (SNP) | VAF 14/76 reads (18%) | SIFT tolerated (0.1); PolyPhen benign (0.099); catalogued as COSV50018348; called by muse, mutect2, varscan2
- ZBTB38 | c.1816C>T p.Q606* | Nonsense Mutation (SNP) | VAF 31/136 reads (23%) | catalogued as COSV58542135; called by muse, mutect2, varscan2
- ZNF23 | c.89T>A p.L30Q | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.94); catalogued as COSV61841061; called by muse, mutect2
- FRG2C | c.190C>T p.P64S | Missense Mutation (SNP) | VAF 65/212 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); called by muse, varscan2
- KIF18A | c.429_436del p.C143* | Nonsense Mutation (DEL) | VAF 27/188 reads (14%) | called by mutect2, pindel, varscan2
- RNF111 | c.1709_1712del p.S570Tfs*48 | Frame Shift Del (DEL) | VAF 13/94 reads (14%) | called by mutect2, pindel, varscan2
- SPON2 | c.986dup p.N329Kfs*42 | Frame Shift Ins (INS) | VAF 27/118 reads (23%) | called by mutect2, pindel, varscan2
- TOMM34 | c.709_710insTAA p.Y237delinsLN | In Frame Ins (INS) | VAF 25/114 reads (22%) | called by mutect2, pindel, varscan2
- VHL | c.345_355del p.L116Qfs*12 | Frame Shift Del (DEL) | VAF 28/129 reads (22%) | called by mutect2, pindel, varscan2
- ABCA9 | c.1638C>T p.H546= | Silent (SNP) | VAF 21/115 reads (18%) | catalogued as COSV60625701; called by muse, mutect2, varscan2
- ACOX3 | c.423C>T p.L141= | Silent (SNP) | VAF 30/129 reads (23%) | catalogued as COSV62712242, COSV62713053; called by muse, mutect2, varscan2
- CYP2C8 | c.909C>T p.S303= | Silent (SNP) | VAF 25/128 reads (20%) | catalogued as COSV64877384; called by muse, mutect2, varscan2
- KRT78 | c.201G>A p.G67= | Silent (SNP) | VAF 12/34 reads (35%) | catalogued as COSV58851945; called by muse, varscan2
- MAP3K9 | c.615C>T p.A205= | Silent (SNP) | VAF 33/101 reads (33%) | catalogued as COSV67121527; called by muse, mutect2, varscan2
- OR2G2 | c.534T>C p.D178= | Silent (SNP) | VAF 26/147 reads (18%) | catalogued as COSV60740730; called by muse, mutect2, varscan2
- PBX3 | c.1101C>T p.V367= | Silent (SNP) | VAF 16/52 reads (31%) | catalogued as rs779924430, COSV60732579; called by muse, mutect2, varscan2
- PLA2G4F | c.2445G>A p.L815= | Silent (SNP) | VAF 8/63 reads (13%) | catalogued as COSV51827245; called by muse, mutect2, varscan2
- RFPL4B | c.288T>C p.D96= | Silent (SNP) | VAF 9/38 reads (24%) | catalogued as rs1430864246, COSV71437440; called by muse, mutect2, varscan2
- ZBTB10 | c.1215T>C p.N405= | Silent (SNP) | VAF 31/123 reads (25%) | catalogued as COSV66947709; called by muse, mutect2, varscan2
- MYB | c.*2A>G | 3'UTR (SNP) | VAF 20/99 reads (20%) | catalogued as COSV57199612; called by muse, mutect2, varscan2
